CCDI case PBBRJL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/adc88cde-e6dc-4078-b8d8-1e42273e4ba8

Demographics
Sex at birth: female; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Undifferentiated sarcoma: ICD-O-3 morphology code: 8805/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 0.2 years (74 days).

Biospecimens (3 samples)
- Sample 0DFA8Y: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFA9C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DFA9F: Tissue type: Tumor; Specimen type: Solid Tissue.
